Somatic mutation profile of tumor specimen 0DRQSZ from CCDI case PBCGVH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Ganglioglioma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 0.9 years (337 days).
Specimen 0DRQSZ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c21840f0-ae35-4be7-b8e2-5c6bda32df97.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRQSN (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f08fdb0c-f4bb-4213-89e2-93a3d69780ab

The open-access MAF lists 3 somatic variants for this specimen: 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EFR3A | c.2187A>G p.E729= | Silent (SNP) | VAF 83/766 reads (11%) | called by muse, mutect2, varscan2
- SDK2 | c.6189C>T p.V2063= | Silent (SNP) | VAF 59/418 reads (14%) | catalogued as rs376496362; called by muse, mutect2, varscan2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 20/186 reads (11%) | called by muse, varscan2
